Somatic mutation profile of tumor specimen ALCH-B4FB-TTP1-A (aliquot ALCH-B4FB-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4FB, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 52.7 years (19,233 days).
Specimen ALCH-B4FB-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33b449d9-284e-4a2f-94b6-34e1ed869f1a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4FB-NB1-A (Blood Derived Normal), aliquot ALCH-B4FB-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/fd37597a-6cf5-4204-80b5-410eec0c62c0

The open-access MAF lists 134 somatic variants for this specimen: 101 protein-altering or splice-affecting, 22 silent, 11 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 85, Silent 22, Nonsense Mutation 11, Intron 4, Splice Site 4, RNA 4, 5'UTR 2, 3'UTR 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>C p.G12A | Missense Mutation (SNP) | VAF 229/558 reads (41%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 30/416 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2
- A2ML1 | c.2769G>C p.K923N | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.81); PolyPhen benign (0); catalogued as COSV55287681; called by muse, mutect2
- ABCC8 | c.1468-2A>G p.X490_splice | Splice Site (SNP) | VAF 11/357 reads (3%) | catalogued as CS162443; called by muse, mutect2
- ACSM2B | c.1424C>A p.P475H | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372282906; called by muse, mutect2
- ALDH8A1 | c.1109G>T p.G370V | Missense Mutation (SNP) | VAF 18/334 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1337809601; called by muse, mutect2
- AP3B2 | c.2890C>T p.R964* (on ENST00000261722; = p.R958* on NM_004644.5) | Nonsense Mutation (SNP) | VAF 9/261 reads (3%) | catalogued as COSV55606450; called by muse, mutect2
- APBA2 | c.1948A>G p.N650D | Missense Mutation (SNP) | VAF 34/502 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.125); catalogued as COSV68790709; called by muse, mutect2
- CCKBR | c.1264G>A p.D422N | Missense Mutation (SNP) | VAF 12/124 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.318); catalogued as rs746523028, COSV58102335, COSV58105140; called by muse, mutect2
- CEP128 | c.2715G>T p.L905F | Missense Mutation (SNP) | VAF 18/628 reads (3%) | SIFT tolerated (0.09); PolyPhen benign (0.03); catalogued as COSV55370215, COSV55372782; called by muse, mutect2
- DCDC2 | c.463C>T p.R155C | Missense Mutation (SNP) | VAF 17/290 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as rs368811969, COSV101015748; called by muse, mutect2
- ERC2 | c.1444G>T p.E482* | Nonsense Mutation (SNP) | VAF 6/121 reads (5%) | catalogued as COSV55607947, COSV99888290; called by muse, mutect2
- GPR50 | c.1279C>T p.P427S | Missense Mutation (SNP) | VAF 8/67 reads (12%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs764148668, COSV54438283; called by muse, mutect2, varscan2
- HOXB9 | c.214G>T p.G72W | Missense Mutation (SNP) | VAF 13/144 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs767687135; called by muse, mutect2, varscan2
- ITGB4 | c.337G>T p.G113C | Missense Mutation (SNP) | VAF 22/298 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52327610; called by muse, mutect2
- KMT2A | c.3545G>T p.R1182L | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV63289075; called by muse, mutect2
- LILRB1 | c.157C>T p.P53S (on ENST00000427581; = p.P17S on NM_006669.6) | Missense Mutation (SNP) | VAF 12/294 reads (4%) | SIFT tolerated (0.49); PolyPhen benign (0.02); catalogued as COSV100208043; called by muse, mutect2
- MYLK | c.3901C>T p.R1301C | Missense Mutation (SNP) | VAF 20/444 reads (5%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.91); catalogued as rs368321325; ClinVar: uncertain significance; called by muse, mutect2
- MYRIP | c.1748G>A p.R583Q | Missense Mutation (SNP) | VAF 21/342 reads (6%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs1003941830, COSV56870587; called by muse, mutect2
- NAP1L3 | c.573G>T p.E191D | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.908); catalogued as COSV59073749; called by muse, mutect2, varscan2
- NECTIN4 | c.400G>A p.A134T | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated (0.44); PolyPhen benign (0.166); catalogued as rs1283713497; called by muse, mutect2
- NLRP4 | c.1101C>A p.S367R | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV56720827; called by muse, mutect2
- NRXN1 | c.1883C>A p.P628H | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1344637711, COSV58446779, COSV58492144; called by muse, mutect2, varscan2
- OCA2 | c.1259G>T p.G420V | Missense Mutation (SNP) | VAF 30/629 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62346076; called by muse, mutect2
- OR10A6 | c.16C>A p.Q6K | Missense Mutation (SNP) | VAF 5/49 reads (10%) | SIFT tolerated (0.35); PolyPhen benign (0.055); catalogued as rs753029150, COSV59165587; called by muse, mutect2, varscan2
- OR2L5 | c.698G>T p.R233M | Missense Mutation (SNP) | VAF 5/98 reads (5%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.981); catalogued as COSV62364430; called by muse, mutect2
- OR5P2 | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 22/354 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs766736798; called by muse, mutect2
- OR9G4 | c.911C>T p.A304V | Missense Mutation (SNP) | VAF 9/152 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.079); catalogued as rs931047201; called by muse, mutect2
- PCDH15 | c.4863C>A p.D1621E (on ENST00000644397 / NM_001354429.2; = p.D1563E on NM_001142771.2) | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as rs1395538084; called by muse, mutect2
- PGLYRP3 | c.217C>T p.H73Y | Missense Mutation (SNP) | VAF 15/290 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.022); catalogued as rs1232890551; called by muse, mutect2
- RASAL2 | c.437G>T p.R146I | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62711852; called by muse, mutect2
- RBM10 | c.2227G>T p.E743* | Nonsense Mutation (SNP) | VAF 8/75 reads (11%) | catalogued as COSV61309421, COSV61312659; called by muse, mutect2
- RYR2 | c.9671C>A p.S3224Y | Missense Mutation (SNP) | VAF 17/280 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); catalogued as COSV63686220; called by muse, mutect2
- SHISA9 | c.868G>A p.A290T | Missense Mutation (SNP) | VAF 16/346 reads (5%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as COSV101428010; called by muse, mutect2
- SLC22A9 | c.1487C>T p.P496L | Missense Mutation (SNP) | VAF 19/320 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.003); catalogued as rs763129817, COSV54170830; called by muse, mutect2
- SNTG2 | c.1259C>G p.T420R | Missense Mutation (SNP) | VAF 9/282 reads (3%) | SIFT deleterious (0.01); PolyPhen benign (0.238); catalogued as COSV57975870; called by muse, mutect2
- TECRL | c.82G>T p.D28Y | Missense Mutation (SNP) | VAF 10/299 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV67086095; called by muse, mutect2
- ZNF521 | c.2223G>T p.L741F | Missense Mutation (SNP) | VAF 12/264 reads (5%) | SIFT tolerated (0.52); PolyPhen probably damaging (1); catalogued as COSV64130054; called by muse, mutect2
- ADAMTS2 | c.2710A>T p.I904F | Missense Mutation (SNP) | VAF 31/517 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.625); called by muse, mutect2
- AHNAK2 | c.12998G>A p.S4333N | Missense Mutation (SNP) | VAF 28/354 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.882); called by muse, mutect2
- BPIFC | c.725A>G p.N242S | Missense Mutation (SNP) | VAF 9/208 reads (4%) | SIFT tolerated (0.7); PolyPhen benign (0.033); called by muse, mutect2
- CACNA1H | c.4807T>G p.Y1603D | Missense Mutation (SNP) | VAF 5/71 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.841); called by muse, mutect2
- CDHR4 | c.364C>T p.L122F | Missense Mutation (SNP) | VAF 20/280 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.135); called by muse, mutect2
- DGKI | c.181G>T p.E61* | Nonsense Mutation (SNP) | VAF 7/88 reads (8%) | called by muse, mutect2
- DOCK4 | c.3137G>T p.C1046F | Missense Mutation (SNP) | VAF 14/288 reads (5%) | SIFT tolerated (0.81); PolyPhen benign (0.006); called by muse, mutect2
- DTX1 | c.724C>A p.P242T | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- FAM200B | c.1048G>T p.V350L | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.793); called by muse, mutect2
- FKBP10 | c.1036C>A p.H346N | Missense Mutation (SNP) | VAF 13/198 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); called by muse, mutect2
- FOCAD | c.906+2T>C p.X302_splice | Splice Site (SNP) | VAF 6/114 reads (5%) | called by muse, mutect2
- FRMPD4 | c.3962C>T p.T1321I | Missense Mutation (SNP) | VAF 3/30 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.942); called by muse, mutect2
- GSX2 | c.476C>A p.A159D | Missense Mutation (SNP) | VAF 16/168 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.261); called by muse, mutect2
- HADHA | c.953C>A p.A318D | Missense Mutation (SNP) | VAF 20/498 reads (4%) | SIFT tolerated (0.1); PolyPhen benign (0.053); called by muse, mutect2
- HMHB1 | c.37+1G>T p.X13_splice | Splice Site (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- KCNA4 | c.146C>A p.A49D | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.005); called by muse, mutect2
- KIAA0586 | c.3814G>T p.E1272* (on ENST00000619416 / NM_001244190.2; = p.E1211* on NM_014749.5) | Nonsense Mutation (SNP) | VAF 6/90 reads (7%) | called by muse, mutect2
- KIF12 | c.31C>G p.L11V | Missense Mutation (SNP) | VAF 16/260 reads (6%) | SIFT tolerated (0.55); PolyPhen benign (0.127); called by muse, mutect2
- KIRREL2 | c.381G>T p.Q127H | Missense Mutation (SNP) | VAF 5/96 reads (5%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.855); called by muse, mutect2
- KRTAP1-4 | c.150G>T p.E50D | Missense Mutation (SNP) | VAF 20/455 reads (4%) | SIFT tolerated (0.53); called by muse, mutect2
- LCP1 | c.1133A>G p.H378R | Missense Mutation (SNP) | VAF 29/639 reads (5%) | SIFT tolerated (0.3); PolyPhen benign (0.045); called by muse, mutect2
- LRP4 | c.2996G>T p.R999L | Missense Mutation (SNP) | VAF 14/111 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.612); called by muse, mutect2, varscan2
- LRRK2 | c.7072G>A p.V2358M | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.681); called by muse, mutect2
- MB21D2 | c.412A>G p.M138V | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.5); called by muse, mutect2
- MYH9 | c.299A>G p.N100S | Missense Mutation (SNP) | VAF 20/274 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MYO18B | c.4753C>A p.L1585I | Missense Mutation (SNP) | VAF 13/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.94); called by muse, mutect2
- MYO5B | c.3703G>T p.G1235C | Missense Mutation (SNP) | VAF 29/479 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, mutect2
- NKAPD1 | c.610A>T p.K204* (on ENST00000280352 / NM_001082970.2; = p.K205* on NM_018195.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 16/386 reads (4%) | called by muse, mutect2
- NPY2R | c.286G>C p.D96H | Missense Mutation (SNP) | VAF 14/257 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- OR10A2 | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 20/424 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); called by muse, mutect2
- OR4K14 | c.162C>A p.C54* | Nonsense Mutation (SNP) | VAF 16/292 reads (5%) | called by muse, mutect2
- OR51V1 | c.253C>A p.L85M | Missense Mutation (SNP) | VAF 12/144 reads (8%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.777); called by muse, mutect2
- OR52B2 | c.636T>G p.D212E | Missense Mutation (SNP) | VAF 18/285 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- OR8J3 | c.841G>T p.V281L | Missense Mutation (SNP) | VAF 10/188 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.181); called by muse, mutect2
- PCDH19 | c.1234G>T p.D412Y | Missense Mutation (SNP) | VAF 10/92 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHA1 | c.343C>A p.Q115K | Missense Mutation (SNP) | VAF 20/266 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.014); called by muse, mutect2
- PCDHB7 | c.115A>T p.T39S | Missense Mutation (SNP) | VAF 16/359 reads (4%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.377); called by muse, mutect2
- PKN2 | c.1120A>C p.K374Q | Missense Mutation (SNP) | VAF 20/270 reads (7%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.541); called by muse, mutect2
- PPP1R21 | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 12/323 reads (4%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.945); called by muse, mutect2
- PXYLP1 | c.62G>A p.S21N | Missense Mutation (SNP) | VAF 38/582 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.112); called by muse, mutect2
- RAE1 | c.397A>G p.I133V | Missense Mutation (SNP) | VAF 22/330 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- REPS2 | c.1133G>T p.W378L | Missense Mutation (SNP) | VAF 13/119 reads (11%) | SIFT tolerated (0.49); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- RYR1 | c.1020C>G p.Y340* | Nonsense Mutation (SNP) | VAF 22/248 reads (9%) | called by muse, mutect2
- SCNN1G | c.644C>T p.A215V | Missense Mutation (SNP) | VAF 22/392 reads (6%) | SIFT tolerated (0.22); PolyPhen benign (0.239); called by muse, mutect2
- SHROOM4 | c.3038C>A p.S1013* | Nonsense Mutation (SNP) | VAF 19/210 reads (9%) | called by muse, mutect2
- SKIDA1 | c.299T>C p.V100A | Missense Mutation (SNP) | VAF 15/218 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- SLC25A6 | c.374_375del p.A125Dfs*123 | Frame Shift Del (DEL) | VAF 27/225 reads (12%) | called by pindel, varscan2
- SLC39A11 | c.221G>T p.G74V | Missense Mutation (SNP) | VAF 20/342 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- SLC7A14 | c.1255T>A p.Y419N | Missense Mutation (SNP) | VAF 27/461 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SNAP91 | c.1558G>T p.A520S | Missense Mutation (SNP) | VAF 22/360 reads (6%) | SIFT tolerated (0.51); PolyPhen benign (0.054); called by muse, mutect2
- SRCIN1 | c.2549G>T p.R850L (on ENST00000621492; = p.R816L on NM_025248.3) | Missense Mutation (SNP) | VAF 10/132 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2
- STXBP5 | c.1933G>T p.V645F | Missense Mutation (SNP) | VAF 8/157 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); called by muse, mutect2
- SUPT6H | c.4209+2T>A p.X1403_splice | Splice Site (SNP) | VAF 6/106 reads (6%) | called by muse, mutect2
- TENM3 | c.5098T>G p.Y1700D | Missense Mutation (SNP) | VAF 17/283 reads (6%) | SIFT tolerated (0.2); PolyPhen benign (0.202); called by muse, mutect2
- TEX101 | c.246C>G p.I82M (on ENST00000598265 / NM_001130011.3; = p.I100M on NM_031451.4) | Missense Mutation (SNP) | VAF 9/108 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.292); called by muse, mutect2
- TRPM1 | c.1581C>A p.H527Q | Missense Mutation (SNP) | VAF 14/346 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2
- WDFY3 | c.7552G>T p.E2518* | Nonsense Mutation (SNP) | VAF 18/314 reads (6%) | called by muse, mutect2
- WEE1 | c.1033A>T p.R345* | Nonsense Mutation (SNP) | VAF 13/190 reads (7%) | called by muse, mutect2
- XIRP1 | c.3539C>A p.P1180Q | Missense Mutation (SNP) | VAF 4/47 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.419); called by muse, mutect2
- ZNF747 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 5/57 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.003); called by muse, mutect2
- ZNF91 | c.163G>T p.A55S | Missense Mutation (SNP) | VAF 10/180 reads (6%) | SIFT tolerated (0.41); PolyPhen benign (0.218); called by muse, mutect2
- ZPBP | c.20G>T p.G7V | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.001); called by muse, mutect2
- ZPBP | c.19G>T p.G7C | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.003); called by muse, mutect2
- ANKRD27 | c.2166A>G p.P722= | Silent (SNP) | VAF 20/492 reads (4%) | called by muse, mutect2
- APOA4 | c.916C>A p.R306= | Silent (SNP) | VAF 27/352 reads (8%) | catalogued as rs201021435, COSV100759330; called by muse, mutect2
- ATP2B3 | c.3099A>T p.L1033= | Silent (SNP) | VAF 20/115 reads (17%) | called by muse, mutect2, varscan2
- C8orf74 | c.453C>A p.L151= | Silent (SNP) | VAF 9/98 reads (9%) | catalogued as COSV58755810; called by muse, mutect2
- CMYA5 | c.4626T>A p.T1542= | Silent (SNP) | VAF 12/178 reads (7%) | called by muse, mutect2
- DAPK1 | c.3387G>T p.V1129= | Silent (SNP) | VAF 24/307 reads (8%) | called by muse, mutect2
- FDXR | c.1095C>T p.R365= (on ENST00000293195 / NM_024417.5; = p.R371= on NM_004110.6) | Silent (SNP) | VAF 16/262 reads (6%) | called by muse, mutect2
- GPR20 | c.189C>T p.I63= | Silent (SNP) | VAF 9/80 reads (11%) | called by muse, mutect2, varscan2
- KCTD14 | c.54C>T p.T18= | Silent (SNP) | VAF 8/130 reads (6%) | catalogued as rs928955596, COSV62001960; called by muse, mutect2
- LCT | c.3354G>T p.G1118= | Silent (SNP) | VAF 5/36 reads (14%) | catalogued as rs1273245715; called by mutect2, varscan2
- LIN28B | c.294G>T p.R98= | Silent (SNP) | VAF 16/310 reads (5%) | catalogued as COSV61493752; called by muse, mutect2
- MRPS27 | c.702G>A p.V234= | Silent (SNP) | VAF 14/198 reads (7%) | catalogued as rs764495347; called by muse, mutect2
- NLRP2 | c.2034C>A p.S678= | Silent (SNP) | VAF 20/374 reads (5%) | catalogued as COSV54755504; called by muse, mutect2
- PCDHA12 | c.2253G>T p.S751= | Silent (SNP) | VAF 12/268 reads (4%) | catalogued as rs570815670, COSV56474896; called by muse, mutect2
- SALL3 | c.1641C>G p.T547= | Silent (SNP) | VAF 10/112 reads (9%) | called by muse, mutect2
- SCN1A | c.1458C>T p.A486= | Silent (SNP) | VAF 24/338 reads (7%) | catalogued as rs562153154; called by muse, mutect2
- SDK1 | c.4392G>A p.L1464= | Silent (SNP) | VAF 9/101 reads (9%) | called by muse, mutect2
- SEC22C | c.201C>T p.D67= | Silent (SNP) | VAF 16/191 reads (8%) | catalogued as rs767063556, COSV99827414; called by muse, mutect2
- TNKS1BP1 | c.5101T>C p.L1701= | Silent (SNP) | VAF 8/102 reads (8%) | called by muse, mutect2
- TRPV1 | c.126G>T p.T42= | Silent (SNP) | VAF 20/342 reads (6%) | catalogued as COSV99440934; called by muse, mutect2
- VAV2 | c.739C>T p.L247= (on ENST00000371850 / NM_001134398.2; = p.L242= on NM_003371.4) | Silent (SNP) | VAF 16/180 reads (9%) | catalogued as COSV64085439; called by muse, mutect2
- ZBTB46 | c.462G>A p.T154= | Silent (SNP) | VAF 15/192 reads (8%) | catalogued as rs573566471, COSV55513131; called by muse, mutect2
- AARS2 | c.*6G>T | 3'UTR (SNP) | VAF 24/219 reads (11%) | called by muse, mutect2, varscan2
- ASB2 | c.168-634C>T | Intron (SNP) | VAF 22/310 reads (7%) | called by muse, mutect2
- GTF2IRD2P1 | n.1846C>A | RNA (SNP) | VAF 23/549 reads (4%) | catalogued as rs1554532657; called by muse, mutect2
- HAS2-AS1 | n.778G>T | RNA (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- KIAA2012 | c.1832-2410G>T | Intron (SNP) | VAF 13/99 reads (13%) | catalogued as rs1424173350; called by muse, varscan2
- MIR125B1 | n.78C>A | RNA (SNP) | VAF 10/231 reads (4%) | called by muse, mutect2
- MUC3A | c.-1C>A | 5'UTR (SNP) | VAF 8/148 reads (5%) | called by muse, mutect2
- NRXN1 | c.3365-110223C>A | Intron (SNP) | VAF 24/273 reads (9%) | catalogued as rs1046856708; called by muse, mutect2
- NRXN1 | c.3365-110224C>A | Intron (SNP) | VAF 24/267 reads (9%) | called by muse, mutect2
- OR5AK4P | n.313G>C | RNA (SNP) | VAF 7/68 reads (10%) | called by muse, mutect2, varscan2
- PJVK | c.-31G>T | 5'UTR (SNP) | VAF 15/260 reads (6%) | called by muse, mutect2
